Somatic mutation profile of tumor specimen TCGA-CG-4469-01A (aliquot TCGA-CG-4469-01A-01D-1158-08) from TCGA case TCGA-CG-4469, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 70.1 years (25,598 days).
Specimen TCGA-CG-4469-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45f3dfe2-a79e-49a9-8f5a-a3532dcf1d9d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-4469-10A (Blood Derived Normal), aliquot TCGA-CG-4469-10A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31e0f058-bd2d-4968-916c-6a0752831d0e

The open-access MAF lists 328 somatic variants for this specimen: 251 protein-altering or splice-affecting, 69 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 229, Silent 69, Nonsense Mutation 12, Frame Shift Del 5, Intron 3, RNA 3, Frame Shift Ins 2, Splice Site 2, Splice Region 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 65/174 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as rs1057519862, COSV54062926; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 25/45 reads (56%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.1656G>C p.K552N | Missense Mutation (SNP) | VAF 28/327 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55933766; called by muse, mutect2
- ABLIM1 | c.2099G>T p.R700I | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV53303004; called by muse, mutect2, varscan2
- AC006059.2 | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT tolerated (0.77); PolyPhen benign (0.06); catalogued as COSV59606315; called by muse, mutect2, varscan2
- ADAM17 | c.292G>C p.V98L | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.098); catalogued as COSV60398142; called by muse, mutect2, varscan2
- ADAM29 | c.2159A>C p.K720T | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV63662266; called by muse, mutect2, varscan2
- ADGRB3 | c.556A>G p.T186A | Missense Mutation (SNP) | VAF 68/182 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV65390310; called by muse, mutect2, varscan2
- ADGRL2 | c.4133T>G p.L1378R (on ENST00000370717 / NM_001366005.1; = p.L1322R on NM_012302.4) | Missense Mutation (SNP) | VAF 50/150 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54659909; called by muse, mutect2, varscan2
- ADGRL4 | c.1589A>T p.H530L | Missense Mutation (SNP) | VAF 96/271 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.573); catalogued as COSV66060828; called by muse, mutect2, varscan2
- AFF2 | c.1324T>G p.L442V | Missense Mutation (SNP) | VAF 667/731 reads (91%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.906); catalogued as COSV53983403, COSV99662068; called by muse, mutect2, varscan2
- AIFM3 | c.134C>T p.T45M | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.23); catalogued as rs767173371, COSV58998410; called by muse, mutect2, varscan2
- AKAP6 | c.5945A>C p.K1982T | Missense Mutation (SNP) | VAF 70/151 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV55209590; called by muse, mutect2, varscan2
- ALK | c.989A>G p.K330R | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as rs781677582, COSV66563187; called by muse, mutect2, varscan2
- ANGPTL4 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.613); catalogued as rs781178060, COSV56844595; called by muse, mutect2, varscan2
- ANKRD30A | c.1204A>G p.T402A (on ENST00000611781; = p.T346A on NM_052997.2) | Missense Mutation (SNP) | VAF 94/259 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.217); catalogued as COSV64607716; called by muse, mutect2, varscan2
- ANKRD30A | c.3051A>C p.K1017N (on ENST00000611781; = p.K961N on NM_052997.2) | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as COSV64603900, COSV64607723, COSV64608830; called by muse, mutect2, varscan2
- APC | c.4262G>A p.S1421N | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57334876, COSV57336346; called by muse, mutect2, varscan2
- APP | c.1306C>T p.Q436* | Nonsense Mutation (SNP) | VAF 54/79 reads (68%) | catalogued as COSV60994936, COSV60996674; called by muse, mutect2, varscan2
- ARHGAP15 | c.852C>G p.H284Q | Missense Mutation (SNP) | VAF 73/205 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV54488001; called by muse, mutect2, varscan2
- ARID1A | c.6023T>G p.L2008R | Missense Mutation (SNP) | VAF 70/94 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61374607; called by muse, mutect2, varscan2
- ASCL4 | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1043669711, COSV60816259; called by muse, mutect2, varscan2
- ASTN2 | c.3599-1G>T p.X1200_splice (on ENST00000313400 / NM_001365069.1; = p.X1149_splice on NM_014010.5) | Splice Site (SNP) | VAF 59/143 reads (41%) | catalogued as COSV56001997; called by muse, mutect2, varscan2
- ATP5IF1 | c.142G>C p.G48R | Missense Mutation (SNP) | VAF 77/199 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55281177; called by muse, mutect2, varscan2
- ATRNL1 | c.2418A>C p.K806N | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.15); catalogued as COSV58081166; called by muse, mutect2, varscan2
- AXDND1 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 99/243 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs368301278; called by muse, mutect2, varscan2
- BEND4 | c.1150A>C p.S384R | Missense Mutation (SNP) | VAF 67/106 reads (63%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.994); catalogued as COSV72469012; called by muse, mutect2, varscan2
- C1orf174 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs764359769, COSV59496251; called by muse, mutect2, varscan2
- C8B | c.413T>G p.L138R | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs955479183, COSV100980703, COSV64777175; called by muse, mutect2, varscan2
- CACNA1I | c.2220A>C p.K740N | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60804492; called by muse, mutect2, varscan2
- CADM1 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.101); catalogued as COSV59006897; called by muse, mutect2, varscan2
- CADPS | c.1913T>G p.L638R | Missense Mutation (SNP) | VAF 101/271 reads (37%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); catalogued as COSV51873616, COSV51879339; called by muse, mutect2, varscan2
- CCDC141 | c.2971C>A p.Q991K | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.072); catalogued as rs748978141, COSV55371373; called by muse, mutect2, varscan2
- CCDC141 | c.2099T>G p.L700R | Missense Mutation (SNP) | VAF 108/301 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.069); catalogued as COSV55371395; called by muse, mutect2, varscan2
- CCN4 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs140971140; called by muse, mutect2, varscan2
- CDC14A | c.1539T>G p.F513L | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60556687; called by muse, mutect2, varscan2
- CDH20 | c.2393C>T p.A798V | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV53007413; called by muse, mutect2, varscan2
- CDH7 | c.721G>T p.G241* | Nonsense Mutation (SNP) | VAF 34/57 reads (60%) | catalogued as COSV59883705; called by muse, mutect2, varscan2
- CDYL2 | c.399G>T p.K133N | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as COSV73647599; called by muse, mutect2, varscan2
- CEP250 | c.4605C>A p.D1535E | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.167); catalogued as COSV61169091; called by muse, mutect2, varscan2
- CHL1 | c.3446G>A p.R1149Q (on ENST00000397491 / NM_001253387.1; = p.R1165Q on NM_006614.4) | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.044); catalogued as rs139892128, COSV99852503; called by muse, mutect2, varscan2
- CHTOP | c.80T>G p.L27R | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.309); catalogued as COSV100904686; called by muse, mutect2, varscan2
- CLMP | c.665G>C p.R222P | Missense Mutation (SNP) | VAF 95/146 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV101507415, COSV71649515; called by muse, mutect2, varscan2
- CMYA5 | c.5583G>T p.L1861F | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.029); catalogued as COSV71404964; called by muse, mutect2, varscan2
- CMYA5 | c.9644A>G p.D3215G | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.07); catalogued as COSV71404965; called by muse, mutect2, varscan2
- CMYA5 | c.12149A>G p.K4050R | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as COSV69745355; called by muse, mutect2, varscan2
- CNOT11 | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 63/175 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56819460; called by muse, mutect2, varscan2
- COIL | c.1696T>A p.S566T | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.061); catalogued as COSV53594455; called by muse, mutect2, varscan2
- COL4A1 | c.488T>G p.L163R | Missense Mutation (SNP) | VAF 87/149 reads (58%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.628); catalogued as COSV65423466; called by muse, mutect2, varscan2
- CSMD1 | c.10580A>T p.E3527V (on ENST00000520002; = p.E3526V on NM_033225.6) | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59303300; called by muse, mutect2, varscan2
- CSMD1 | c.7387G>C p.G2463R (on ENST00000520002; = p.G2462R on NM_033225.6) | Missense Mutation (SNP) | VAF 91/160 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59303357; called by muse, mutect2, varscan2
- CSMD1 | c.5728A>C p.T1910P (on ENST00000520002; = p.T1909P on NM_033225.6) | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59303381; called by muse, mutect2, varscan2
- CSMD1 | c.2530T>G p.F844V (on ENST00000520002; = p.F843V on NM_033225.6) | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated (0.13); PolyPhen benign (0.077); catalogued as COSV59303410; called by muse, mutect2, varscan2
- CSMD1 | c.755A>C p.D252A | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV68187279; called by muse, mutect2, varscan2
- CSMD3 | c.9019T>C p.S3007P (on ENST00000297405 / NM_001363185.1; = p.S2838P on NM_052900.3) | Missense Mutation (SNP) | VAF 89/104 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV52142747; called by muse, mutect2, varscan2
- CSMD3 | c.2816+1G>T p.X939_splice (on ENST00000297405 / NM_001363185.1; = p.X835_splice on NM_052900.3) | Splice Site (SNP) | VAF 12/24 reads (50%) | catalogued as COSV52142765; called by muse, mutect2, varscan2
- CSMD3 | c.1885T>G p.L629V (on ENST00000297405 / NM_001363185.1; = p.L525V on NM_052900.3) | Missense Mutation (SNP) | VAF 90/188 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52142777; called by muse, mutect2, varscan2
- CSTF2 | c.523G>C p.A175P | Missense Mutation (SNP) | VAF 103/140 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63376184; called by muse, mutect2, varscan2
- CTNNB1 | c.1346del p.R449Lfs*23 | Frame Shift Del (DEL) | VAF 96/286 reads (34%) | catalogued as COSV62688158; called by mutect2, pindel, varscan2
- CTNND2 | c.3575A>C p.K1192T | Missense Mutation (SNP) | VAF 84/191 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100481783, COSV58877118; called by muse, mutect2, varscan2
- DAAM1 | c.2026C>A p.L676M | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.95); catalogued as COSV62835276; called by muse, mutect2, varscan2
- DACH2 | c.1757A>C p.N586T | Missense Mutation (SNP) | VAF 35/49 reads (71%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.013); catalogued as COSV64165353; called by muse, mutect2, varscan2
- DENND2C | c.1544A>T p.Q515L (on ENST00000393274 / NM_001256404.2; = p.Q458L on NM_198459.4) | Missense Mutation (SNP) | VAF 97/215 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV67920850; called by muse, mutect2, varscan2
- DGKA | c.1210C>T p.R404* | Nonsense Mutation (SNP) | VAF 98/237 reads (41%) | catalogued as rs759785992, COSV59385242; called by muse, mutect2, varscan2
- DHX37 | c.1396A>T p.M466L | Missense Mutation (SNP) | VAF 149/393 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV58133176; called by muse, mutect2, varscan2
- DNAH11 | c.8669T>G p.L2890R | Missense Mutation (SNP) | VAF 66/282 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60948819; called by muse, mutect2, varscan2
- DNAH9 | c.9017C>T p.T3006I | Missense Mutation (SNP) | VAF 52/83 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs1567826786, COSV52343181; called by muse, mutect2, varscan2
- DRC7 | c.512A>G p.H171R | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV61053917; called by muse, mutect2, varscan2
- EFCAB1 | c.72A>C p.E24D | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50618028; called by muse, mutect2, varscan2
- ELMO1 | c.953A>G p.Q318R | Missense Mutation (SNP) | VAF 70/286 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV60300274; called by muse, mutect2, varscan2
- ELOA | c.2086G>A p.A696T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV69309804; called by muse, mutect2, varscan2
- ERBB4 | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53516241, COSV53518427; called by muse, mutect2, varscan2
- ERMAP | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs563298024, COSV60273887; called by muse, mutect2, varscan2
- F5 | c.1029G>T p.Q343H | Missense Mutation (SNP) | VAF 117/245 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV63122480; called by muse, mutect2, varscan2
- FAAH2 | c.695G>C p.R232P | Missense Mutation (SNP) | VAF 152/467 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66506574, COSV66507245; called by muse, mutect2, varscan2
- FAT4 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 15/50 reads (30%) | catalogued as COSV67883474; called by muse, mutect2, varscan2
- FAT4 | c.5977A>C p.T1993P | Missense Mutation (SNP) | VAF 130/342 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.23); catalogued as COSV58677989; called by muse, varscan2
- FAT4 | c.10643A>C p.Y3548S | Missense Mutation (SNP) | VAF 118/296 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58678000; called by muse, mutect2, varscan2
- FBN3 | c.5234G>A p.R1745H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.93); catalogued as rs779127217, COSV54457032; called by muse, mutect2, varscan2
- FBXO10 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52832273; called by muse, mutect2, varscan2
- FLG | c.9835G>A p.A3279T | Missense Mutation (SNP) | VAF 415/1078 reads (38%) | SIFT tolerated (0.96); PolyPhen benign (0.037); catalogued as rs115482787, COSV64246012; called by muse, mutect2, varscan2
- FLRT2 | c.1684T>G p.F562V | Missense Mutation (SNP) | VAF 88/217 reads (41%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.589); catalogued as COSV58139048; called by muse, mutect2, varscan2
- FOXR2 | c.587A>C p.N196T | Missense Mutation (SNP) | VAF 63/85 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59258105; called by muse, mutect2, varscan2
- GABBR1 | c.1380G>T p.E460D | Missense Mutation (SNP) | VAF 90/247 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.119); catalogued as COSV63541776; called by muse, mutect2, varscan2
- GATA3 | c.1153T>G p.F385V | Missense Mutation (SNP) | VAF 69/195 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as COSV60516959; called by muse, mutect2, varscan2
- GFRA1 | c.923G>T p.S308I | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs761924829, COSV62604160; called by muse, mutect2, varscan2
- GFRA1 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as rs376230694; called by muse, mutect2, varscan2
- GPR162 | c.839A>G p.Y280C | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50589871; called by muse, mutect2, varscan2
- GPRC6A | c.1037T>G p.L346R | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV59952322; called by muse, mutect2, varscan2
- GRIK4 | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs773509095, COSV70801293; called by muse, mutect2, varscan2
- GUF1 | c.412C>T p.L138F | Missense Mutation (SNP) | VAF 45/62 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55782019; called by muse, mutect2, varscan2
- HEYL | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs757763641, COSV65721451; called by muse, mutect2, varscan2
- HMCN1 | c.3080A>C p.K1027T | Missense Mutation (SNP) | VAF 108/240 reads (45%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.505); catalogued as COSV54889062, COSV99623133, COSV99637782; called by muse, mutect2, varscan2
- HTR1A | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 81/204 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100109037; called by muse, mutect2, varscan2
- IGF1R | c.3865G>A p.E1289K | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.393); catalogued as rs1356080771, COSV51276334; called by muse, mutect2, varscan2
- IGSF1 | c.2047C>T p.L683F | Missense Mutation (SNP) | VAF 65/239 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV63836823; called by muse, mutect2, varscan2
- IGSF10 | c.5686T>G p.L1896V | Missense Mutation (SNP) | VAF 63/176 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.836); catalogued as COSV56783370; called by muse, mutect2, varscan2
- IL1RAPL2 | c.690A>C p.K230N | Missense Mutation (SNP) | VAF 60/74 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV61149649; called by muse, mutect2, varscan2
- IMP4 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as rs777698449, COSV52091142; called by muse, mutect2, varscan2
- KCNA1 | c.1303T>G p.L435V | Missense Mutation (SNP) | VAF 196/528 reads (37%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.022); catalogued as rs745972916, COSV66836707; called by mutect2, varscan2
- KCNB2 | c.264C>A p.F88L | Missense Mutation (SNP) | VAF 120/223 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV73049579; called by muse, mutect2, varscan2
- KCNH2 | c.1565G>A p.G522E | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs778103101, COSV51132178; called by muse, mutect2, varscan2
- KCNRG | c.313C>A p.P105T | Missense Mutation (SNP) | VAF 51/486 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV53948654; called by muse, mutect2, varscan2
- KHDRBS3 | c.934A>G p.T312A | Missense Mutation (SNP) | VAF 23/274 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV63416407; called by muse, mutect2
- KIFC1 | c.208C>G p.P70A | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV65737421; called by muse, mutect2, varscan2
- KRT33A | c.1083G>C p.E361D | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.157); catalogued as COSV50366044; called by muse, mutect2, varscan2
- KRTAP9-3 | c.35C>A p.T12N | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT deleterious (0.01); catalogued as rs1568056686, COSV66646535; called by muse, mutect2, varscan2
- LAMA1 | c.6338C>T p.A2113V | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV67534483; called by muse, mutect2, varscan2
- LCMT2 | c.172G>A p.V58I | Missense Mutation (SNP) | VAF 65/170 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.047); catalogued as rs931873599, COSV59789962; called by muse, mutect2, varscan2
- LONRF2 | c.947C>G p.A316G | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.055); catalogued as COSV66540163; called by muse, mutect2, varscan2
- LRIG2 | c.2304G>A p.M768I | Missense Mutation (SNP) | VAF 70/196 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.401); catalogued as COSV63161533; called by muse, mutect2, varscan2
- LRP1B | c.3981A>T p.E1327D | Missense Mutation (SNP) | VAF 70/184 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as COSV67202080, COSV67279079; called by muse, mutect2, varscan2
- MAB21L1 | c.920T>G p.L307R | Missense Mutation (SNP) | VAF 156/295 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV59771790; called by muse, mutect2, varscan2
- MAGEB18 | c.581T>A p.I194N | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV57463607; called by muse, mutect2, varscan2
- MAPK8 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 76/222 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.808); catalogued as COSV64408691; called by muse, mutect2, varscan2
- MC4R | c.259G>C p.A87P | Missense Mutation (SNP) | VAF 63/96 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55351685; called by muse, mutect2, varscan2
- MDGA2 | c.893A>C p.K298T | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.233); catalogued as COSV62085113; called by muse, mutect2
- MMP21 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs766839501, COSV64289093; called by muse, mutect2, varscan2
- MYCT1 | c.163A>C p.S55R | Missense Mutation (SNP) | VAF 49/76 reads (64%) | SIFT tolerated (0.21); PolyPhen benign (0.366); catalogued as COSV65890731, COSV65891152; called by muse, mutect2, varscan2
- NAALADL2 | c.220C>G p.L74V | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs1219306240, COSV70794630, COSV70795037; called by muse, mutect2, varscan2
- NBEA | c.5849A>C p.N1950T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.094); catalogued as COSV59771770; called by muse, mutect2
- NCAM2 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.107); catalogued as rs1309764919, COSV53065808; called by muse, mutect2, varscan2
- NGF | c.134A>C p.D45A | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV65687376; called by muse, mutect2, varscan2
- NKAIN2 | c.300T>A p.N100K | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63652802; called by muse, mutect2, varscan2
- NLRP9 | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs371355203; called by muse, mutect2, varscan2
- NOX4 | c.946A>C p.S316R | Missense Mutation (SNP) | VAF 76/205 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV54450239; called by muse, mutect2, varscan2
- NR3C2 | c.2662A>G p.S888G | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV60987894; called by muse, mutect2, varscan2
- NRK | c.1454T>G p.V485G | Missense Mutation (SNP) | VAF 35/50 reads (70%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV54592881; called by muse, mutect2, varscan2
- NRXN3 | c.1162A>T p.S388C (on ENST00000335750 / NM_001330195.2; = p.S15C on NM_004796.6) | Missense Mutation (SNP) | VAF 86/263 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV59732025; called by muse, mutect2, varscan2
- NUAK1 | c.1465G>T p.E489* | Nonsense Mutation (SNP) | VAF 59/161 reads (37%) | catalogued as COSV54601955; called by muse, mutect2, varscan2
- OAF | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV61109019; called by muse, mutect2, varscan2
- OPRPN | c.726A>C p.K242N | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV101271105, COSV68192676; called by muse, mutect2, varscan2
- OR2F2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 167/286 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs773175092, COSV68832666; called by muse, mutect2, varscan2
- OR2G2 | c.418C>T p.H140Y | Missense Mutation (SNP) | VAF 166/424 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs1252889298, COSV60739969; called by muse, mutect2, varscan2
- OR2L2 | c.9T>G p.N3K | Missense Mutation (SNP) | VAF 98/224 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV63550757; called by muse, mutect2, varscan2
- OR4C12 | c.260A>C p.K87T | Missense Mutation (SNP) | VAF 85/205 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as COSV58859624, COSV58860140; called by muse, mutect2, varscan2
- OR4C16 | c.640T>G p.F214V | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1565052625, COSV58941376; called by muse, mutect2, varscan2
- OR51B4 | c.43T>C p.F15L | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1032313035, COSV66517043; called by muse, mutect2, varscan2
- OR52L1 | c.477A>G p.I159M | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV59986439; called by muse, mutect2
- OR5H14 | c.919A>T p.R307* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as COSV71193731; called by muse, mutect2, varscan2
- OR5L2 | c.665T>C p.L222P | Missense Mutation (SNP) | VAF 58/220 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65723346; called by muse, mutect2, varscan2
- OR5M11 | c.532T>C p.C178R | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV73141692; called by muse, mutect2, varscan2
- OR8D1 | c.253T>C p.F85L | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as rs749419767, COSV100766621, COSV63441871; called by muse, mutect2, varscan2
- OR8G5 | c.32A>C p.K11T | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as COSV100422739, COSV58379665; called by muse, mutect2, varscan2
- OR8H3 | c.167T>G p.L56R | Missense Mutation (SNP) | VAF 255/821 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100538791, COSV57908101, COSV57910433; called by muse, mutect2, varscan2
- OR8K3 | c.839T>G p.V280G | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV57131104; called by muse, mutect2, varscan2
- PCDHA11 | c.2227G>A p.A743T | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.033); catalogued as COSV56489368; called by muse, mutect2, varscan2
- PCDHA13 | c.916G>C p.G306R | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.651); catalogued as COSV56489380; called by muse, mutect2, varscan2
- PCDHB11 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 157/398 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.306); catalogued as rs782664719, COSV61310634, COSV61313865; called by muse, mutect2, varscan2
- PCDHB8 | c.392C>A p.S131Y | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.684); catalogued as COSV50765566; called by muse, mutect2
- PCGF5 | c.444T>A p.N148K | Missense Mutation (SNP) | VAF 67/198 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.328); catalogued as COSV60237571; called by muse, mutect2, varscan2
- PCLO | c.2346A>C p.K782N | Missense Mutation (SNP) | VAF 203/355 reads (57%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.109); catalogued as COSV61625467; called by muse, mutect2, varscan2
- PCLO | c.1015A>C p.T339P | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as rs768105451, COSV61622484; called by muse, mutect2, varscan2
- PDLIM7 | c.136G>A p.V46M | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); catalogued as rs1351332502, COSV62883128; called by muse, mutect2, varscan2
- PEG3 | c.892T>A p.S298T | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as COSV55629594; called by muse, mutect2, varscan2
- PEG3 | c.422A>C p.D141A | Missense Mutation (SNP) | VAF 67/146 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV55629604; called by muse, mutect2, varscan2
- PGM1 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.904); catalogued as COSV64300357; called by muse, mutect2, varscan2
- PKHD1 | c.9824T>C p.L3275P | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100582291, COSV61862672; called by muse, mutect2, varscan2
- POLRMT | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 98/192 reads (51%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as COSV73933168; called by muse, mutect2, varscan2
- PRKG1 | c.1787A>G p.K596R | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT tolerated (0.96); PolyPhen benign (0.028); catalogued as COSV64768507, COSV64771842; called by muse, mutect2, varscan2
- PSMG2 | c.620T>G p.F207C | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58288027; called by muse, mutect2, varscan2
- PTGDR2 | c.349G>C p.A117P | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV57124773; called by muse, mutect2, varscan2
- PTPRC | c.1423A>T p.M475L | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV61408875; called by muse, mutect2, varscan2
- PTPRG | c.2364G>C p.E788D | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.034); catalogued as COSV55634989; called by muse, mutect2, varscan2
- PTPRZ1 | c.5537G>T p.S1846I | Missense Mutation (SNP) | VAF 47/222 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV66433848, COSV66434858; called by muse, mutect2, varscan2
- RIMS1 | c.413A>C p.K138T | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV53448759; called by muse, mutect2, varscan2
- RMC1 | c.643A>G p.M215V | Missense Mutation (SNP) | VAF 43/61 reads (70%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs148477145; called by muse, mutect2, varscan2
- RNASE2 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 112/282 reads (40%) | catalogued as rs755835358, COSV58941005; called by muse, mutect2, varscan2
- RNF43 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 27/49 reads (55%) | catalogued as COSV68457533; called by muse, mutect2, varscan2
- ROR2 | c.1101C>A p.N367K | Missense Mutation (SNP) | VAF 55/149 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV65217912, COSV65222800; called by muse, mutect2, varscan2
- RTL3 | c.767T>G p.V256G | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.07); PolyPhen benign (0.106); catalogued as COSV58183628; called by muse, mutect2, varscan2
- RTL3 | c.466T>G p.S156A | Missense Mutation (SNP) | VAF 44/51 reads (86%) | SIFT tolerated (1); PolyPhen benign (0.108); catalogued as COSV58183634; called by muse, mutect2, varscan2
- RYR1 | c.5987G>A p.R1996H | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1291363715, COSV62093571; called by muse, mutect2, varscan2
- RYR2 | c.1357A>C p.S453R | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.877); catalogued as COSV63675761; called by muse, mutect2
- SACS | c.3190C>T p.L1064F | Missense Mutation (SNP) | VAF 250/444 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs776315930, COSV66537810; called by muse, mutect2, varscan2
- SEMA6D | c.2908C>A p.Q970K (on ENST00000316364 / NM_153618.2; = p.Q908K on NM_020858.2) | Missense Mutation (SNP) | VAF 92/231 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.2); catalogued as COSV60374956; called by muse, mutect2, varscan2
- SETDB1 | c.3766C>T p.R1256W (on ENST00000271640 / NM_001366417.1; = p.R1255W on NM_012432.4) | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1395729846, COSV54976407; called by muse, mutect2, varscan2
- SH2B2 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 58/90 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0.242); catalogued as COSV60825977; called by muse, mutect2, varscan2
- SH3GL2 | c.479A>C p.K160T | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66049274; called by muse, mutect2, varscan2
- SLC25A37 | c.841G>T p.G281C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99264009; called by muse, mutect2, varscan2
- SLC26A2 | c.2011C>T p.R671C | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.081); catalogued as rs376837549; called by muse, mutect2, varscan2
- SLC9A4 | c.514G>T p.G172C | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs1372068489, COSV54832000; called by muse, mutect2, varscan2
- SLCO1C1 | c.892A>G p.S298G | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV56870650; called by muse, mutect2, varscan2
- SLCO1C1 | c.2020A>C p.S674R | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV56869580; called by muse, mutect2, varscan2
- SLCO6A1 | c.1711T>C p.C571R | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1226269267, COSV65808138; called by muse, mutect2, varscan2
- SLITRK5 | c.1990T>C p.S664P | Missense Mutation (SNP) | VAF 59/130 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61521901; called by muse, mutect2, varscan2
- SMAD4 | c.178G>C p.A60P | Missense Mutation (SNP) | VAF 83/145 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61686406; called by muse, mutect2, varscan2
- SNTG2 | c.1102T>G p.L368V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV57975647; called by muse, mutect2, varscan2
- SPACA1 | c.339A>C p.E113D | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV99389570; called by muse, mutect2, varscan2
- SPACA1 | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 38/117 reads (32%) | catalogued as COSV99389571; called by muse, mutect2, varscan2
- SPANXN1 | c.100T>G p.L34V | Missense Mutation (SNP) | VAF 177/192 reads (92%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.68); catalogued as COSV100979279, COSV65121824, COSV65122226; called by muse, mutect2, varscan2
- SPPL2A | c.1168C>G p.P390A | Missense Mutation (SNP) | VAF 92/211 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55940550; called by muse, mutect2, varscan2
- SPTA1 | c.2199G>C p.E733D | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63751117; called by muse, mutect2, varscan2
- SRCAP | c.9359C>T p.T3120I | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV52669856; called by muse, mutect2, varscan2
- SSTR4 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 65/226 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV54797036, COSV99658469; called by muse, mutect2, varscan2
- STXBP4 | c.1626G>T p.E542D | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV64464287; called by muse, mutect2, varscan2
- STYXL2 | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs754706168, COSV54803783; called by muse, mutect2, varscan2
- SUN5 | c.605A>C p.K202T | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62180590; called by muse, mutect2, varscan2
- SUPT16H | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 82/187 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.035); catalogued as rs775004031, COSV53523401; called by muse, mutect2, varscan2
- SUPT20HL1 | c.2078C>G p.S693W | Missense Mutation (SNP) | VAF 63/129 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770602391; called by muse, mutect2, varscan2
- SV2A | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100975186, COSV64965032; called by muse, mutect2, varscan2
- TBC1D15 | c.1158G>A p.M386I | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV59848516; called by muse, mutect2, varscan2
- TBX3 | c.1234G>A p.V412I (on ENST00000257566 / NM_016569.4; = p.V392I on NM_005996.4) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV57470335; called by muse, mutect2, varscan2
- TERF1 | c.55A>G p.R19G | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs769878289, COSV52577368; called by muse, mutect2, varscan2
- TFAP2D | c.161A>C p.E54A | Missense Mutation (SNP) | VAF 111/290 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as COSV50411650, COSV50433932; called by muse, mutect2, varscan2
- TLR4 | c.1382T>G p.V461G (on ENST00000355622 / NM_138554.5; = p.V421G on NM_003266.4) | Missense Mutation (SNP) | VAF 86/218 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62922815; called by muse, mutect2, varscan2
- TMEM132D | c.2623A>G p.N875D | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67159644; called by muse, mutect2, varscan2
- TMPRSS13 | c.502C>T p.L168F | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as rs200625070, COSV70626028; called by muse, mutect2, varscan2
- TMTC3 | c.112G>C p.D38H | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57123254; called by muse, mutect2, varscan2
- TNNI2 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1312926, COSV53289117; called by muse, mutect2, varscan2
- TRANK1 | c.2711A>T p.H904L | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57145774; called by muse, mutect2, varscan2
- TRPA1 | c.2945T>G p.L982R | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51558636; called by muse, mutect2
- TRPC4 | c.354C>A p.H118Q | Missense Mutation (SNP) | VAF 121/229 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV58995924; called by muse, mutect2, varscan2
- TTN | c.39803T>C p.L13268P (on ENST00000591111; = p.L5844P on NM_003319.4) | Missense Mutation (SNP) | VAF 66/186 reads (35%) | PolyPhen probably damaging (0.999); catalogued as COSV100623612, COSV59967055; called by muse, mutect2, varscan2
- TTN | c.37817A>C p.E12606A (on ENST00000591111; = p.E5182A on NM_003319.4) | Missense Mutation (SNP) | VAF 32/72 reads (44%) | PolyPhen benign (0.003); catalogued as COSV59967074; called by muse, mutect2, varscan2
- TTN | c.17750A>C p.K5917T (on ENST00000591111; = p.K4990T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/189 reads (42%) | PolyPhen benign (0.399); catalogued as COSV59967098; called by muse, mutect2, varscan2
- UACA | c.3902C>A p.T1301K | Missense Mutation (SNP) | VAF 78/189 reads (41%) | SIFT tolerated (0.4); PolyPhen benign (0.159); catalogued as COSV59854650; called by muse, mutect2, varscan2
- UBAP2 | c.3163G>C p.A1055P | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV54288534; called by muse, mutect2, varscan2
- UNC5C | c.748A>G p.S250G | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV71658900; called by muse, mutect2, varscan2
- USP13 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV55864144; called by muse, mutect2, varscan2
- WDR49 | c.1361T>G p.L454R (on ENST00000308378 / NM_001366158.1; = p.L795R on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV57705031; called by muse, mutect2, varscan2
- XPA | c.174C>T p.G58= | Splice Region (SNP) | VAF 76/180 reads (42%) | catalogued as COSV64305072; called by muse, mutect2, varscan2
- ZCWPW2 | c.801A>C p.E267D | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV67497401; called by muse, mutect2, varscan2
- ZDHHC4 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 154/554 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs145005587; called by muse, mutect2, varscan2
- ZDHHC4 | c.357T>A p.C119* | Nonsense Mutation (SNP) | VAF 186/552 reads (34%) | catalogued as COSV60106214; called by muse, mutect2, varscan2
- ZIC4 | c.185T>C p.L62P | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as COSV67170786; called by muse, mutect2, varscan2
- ZKSCAN8 | c.1311T>G p.N437K | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.742); catalogued as COSV57637400; called by muse, mutect2, varscan2
- ZNF208 | c.1163A>G p.K388R | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.996); catalogued as COSV68101616, COSV68103083; called by muse, mutect2, varscan2
- ZNF302 | c.205A>T p.K69* (on ENST00000627982; = p.K68* on NM_018443.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 61/160 reads (38%) | catalogued as COSV71063348; called by muse, mutect2, varscan2
- ZNF32 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.151); catalogued as COSV65641548; called by muse, mutect2, varscan2
- ZNF398 | c.1825G>T p.G609C (on ENST00000475153 / NM_170686.3; = p.G438C on NM_020781.4) | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV60064906; called by muse, varscan2
- ZNF454 | c.1322C>G p.T441R | Missense Mutation (SNP) | VAF 74/195 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as rs756598937, COSV60767797; called by muse, mutect2, varscan2
- ZNF492 | c.50A>C p.K17T | Missense Mutation (SNP) | VAF 86/264 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV71761752, COSV71761974; called by muse, varscan2
- ZNF514 | c.844C>T p.H282Y | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54633609; called by muse, mutect2, varscan2
- ZNF551 | c.1199T>G p.F400C | Missense Mutation (SNP) | VAF 70/179 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56591984; called by muse, mutect2, varscan2
- ZNF568 | c.27C>A p.S9R | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as COSV61740948; called by muse, mutect2, varscan2
- ZNF596 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57653387, COSV57655026; called by muse, mutect2, varscan2
- ZNF804B | c.1346A>C p.K449T | Missense Mutation (SNP) | VAF 50/219 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV60822486, COSV60862548; called by muse, mutect2, varscan2
- ZNF83 | c.944A>C p.K315T | Missense Mutation (SNP) | VAF 108/272 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56529226; called by muse, varscan2
- ZNF93 | c.1116A>C p.E372D | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.632); catalogued as COSV59374842; called by muse, mutect2, varscan2
- AKAP13 | c.3448_3461del p.P1150Sfs*2 | Frame Shift Del (DEL) | VAF 28/128 reads (22%) | called by mutect2, pindel, varscan2
- CPS1 | c.2422_2423del p.S808Ffs*28 | Frame Shift Del (DEL) | VAF 120/442 reads (27%) | called by pindel, varscan2
- ELF3 | c.636_640dup p.G214Afs*42 | Frame Shift Ins (INS) | VAF 33/80 reads (41%) | called by mutect2, pindel, varscan2
- FCGBP | c.6952C>G p.Q2318E | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCND3 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 63/135 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIR3DL3 | c.791T>G p.L264R | Missense Mutation (SNP) | VAF 116/321 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- OGFRL1 | c.1035dup p.A346Sfs*15 | Frame Shift Ins (INS) | VAF 49/161 reads (30%) | called by mutect2, pindel, varscan2
- PRAMEF20 | c.448T>G p.F150V | Missense Mutation (SNP) | VAF 264/706 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- R3HCC1L | c.1460del p.L487Wfs*8 | Frame Shift Del (DEL) | VAF 55/154 reads (36%) | called by pindel, varscan2
- SYT3 | c.609del p.S204Vfs*35 | Frame Shift Del (DEL) | VAF 32/109 reads (29%) | called by mutect2, pindel, varscan2
- TRAJ36 | c.16A>T p.N6Y | Missense Mutation (SNP) | VAF 44/134 reads (33%) | called by muse, mutect2, varscan2
- ACTN1 | c.2100C>T p.I700= | Silent (SNP) | VAF 78/207 reads (38%) | catalogued as rs577992605, COSV51988240, COSV51989932; called by muse, mutect2, varscan2
- ADAMTSL3 | c.6T>G p.A2= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV54442326; called by muse, mutect2, varscan2
- ADGRG4 | c.2097T>C p.T699= | Silent (SNP) | VAF 260/277 reads (94%) | catalogued as COSV54952798; called by muse, mutect2, varscan2
- ALK | c.2193C>T p.T731= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs56017149, COSV101200710, COSV66583041; ClinVar: likely benign; called by muse, mutect2, varscan2
- ATP2B3 | c.738C>T p.G246= | Silent (SNP) | VAF 112/129 reads (87%) | catalogued as COSV54843497; called by muse, mutect2, varscan2
- BDP1 | c.7779T>C p.Y2593= | Silent (SNP) | VAF 130/341 reads (38%) | catalogued as COSV62430414; called by muse, mutect2, varscan2
- C4orf50 | c.354C>T p.N118= (on ENST00000324058; = p.N1350= on NM_001364689.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 139/217 reads (64%) | catalogued as rs755853988, COSV60688051; called by muse, mutect2, varscan2
- CCDC180 | c.1224C>T p.C408= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as COSV63828796; called by muse, mutect2
- CD33 | c.1068C>T p.T356= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as rs61736476; called by muse, mutect2, varscan2
- CEP85L | c.1275T>G p.T425= | Silent (SNP) | VAF 60/148 reads (41%) | catalogued as COSV63821740; called by muse, mutect2, varscan2
- CLDN10 | c.588G>A p.G196= | Silent (SNP) | VAF 36/143 reads (25%) | catalogued as COSV54823846; called by muse, mutect2, varscan2
- CNTF | c.271T>C p.L91= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as COSV60158171; called by muse, mutect2, varscan2
- COCH | c.861T>C p.F287= (on ENST00000216361 / NM_001347720.1; = p.F222= on NM_004086.3) | Silent (SNP) | VAF 57/134 reads (43%) | catalogued as COSV53550193; called by muse, mutect2, varscan2
- COL11A1 | c.2520A>G p.P840= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as rs942911563, COSV62178194; called by muse, mutect2, varscan2
- CUX2 | c.3420C>T p.T1140= | Silent (SNP) | VAF 64/199 reads (32%) | catalogued as rs376748122; called by muse, mutect2, varscan2
- DNAH1 | c.6342C>T p.S2114= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs758777405, COSV70227630; called by muse, mutect2, varscan2
- FAT4 | c.13794T>C p.T4598= | Silent (SNP) | VAF 41/142 reads (29%) | catalogued as COSV58678014; called by muse, mutect2, varscan2
- FHL5 | c.513T>G p.T171= | Silent (SNP) | VAF 178/470 reads (38%) | catalogued as COSV58734888, COSV58736483, COSV58740353; called by muse, varscan2
- FRAS1 | c.642G>A p.P214= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs532528605, COSV53600358; called by muse, mutect2, varscan2
- FRMD1 | c.525C>T p.C175= | Silent (SNP) | VAF 27/37 reads (73%) | catalogued as rs376956774; called by muse, mutect2, varscan2
- GIPC3 | c.639G>A p.A213= | Silent (SNP) | VAF 53/139 reads (38%) | catalogued as rs371566042; called by muse, mutect2, varscan2
- GNAO1 | c.399C>T p.G133= | Silent (SNP) | VAF 36/100 reads (36%) | catalogued as rs556058539, COSV52612417; called by muse, mutect2, varscan2
- GOLGB1 | c.3549C>G p.A1183= | Silent (SNP) | VAF 193/452 reads (43%) | catalogued as COSV61463677; called by muse, mutect2, varscan2
- HBE1 | c.210T>G p.T70= | Silent (SNP) | VAF 62/156 reads (40%) | catalogued as rs202129332, COSV53079805, COSV53080603; called by muse, mutect2, varscan2
- HDHD5 | c.624C>T p.I208= (on ENST00000336737 / NM_033070.3; = p.I178= on NM_017829.5) | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as rs754895790, COSV50084886; called by muse, mutect2
- HGFAC | c.672C>T p.H224= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs372890331; called by muse, mutect2, varscan2
- ICE1 | c.3459G>A p.T1153= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs544295645, COSV56821893; called by muse, mutect2, varscan2
- KCNJ12 | c.432C>T p.I144= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs555222028, COSV59165155; called by muse, mutect2, varscan2
- KCNN2 | c.120C>T p.V40= (on ENST00000264773; = p.V252= on NM_021614.4) | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as rs755351182, COSV99300043; called by muse, varscan2
- KDM3B | c.555A>G p.Q185= | Silent (SNP) | VAF 67/195 reads (34%) | catalogued as COSV58689552; called by muse, mutect2, varscan2
- LILRB3 | c.162G>A p.E54= | Silent (SNP) | VAF 97/392 reads (25%) | called by muse, mutect2, varscan2
- LILRB4 | c.126G>A p.G42= | Silent (SNP) | VAF 98/234 reads (42%) | catalogued as rs775831330, COSV54404356; called by muse, mutect2, varscan2
- LIMK1 | c.1446G>A p.A482= | Silent (SNP) | VAF 34/117 reads (29%) | catalogued as rs782401601, COSV60280609; called by muse, mutect2, varscan2
- LRP12 | c.2340T>C p.S780= | Silent (SNP) | VAF 272/321 reads (85%) | catalogued as COSV52627356; called by muse, mutect2, varscan2
- MED12L | c.5919G>A p.P1973= | Silent (SNP) | VAF 75/192 reads (39%) | catalogued as rs143048351; called by muse, mutect2, varscan2
- MEIOC | c.1110G>A p.K370= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as rs769194089, COSV63439684; called by muse, mutect2, varscan2
- MTSS2 | c.1719C>T p.T573= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs746621800, COSV55380396; called by muse, varscan2
- NKX2-5 | c.744C>T p.Y248= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as rs758539727, COSV61298684; called by muse, mutect2, varscan2
- NPAS4 | c.2223G>A p.S741= | Silent (SNP) | VAF 61/166 reads (37%) | catalogued as rs151135507; called by muse, mutect2, varscan2
- OBSL1 | c.726G>A p.A242= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as rs1211145050, COSV54716375; called by muse, mutect2, varscan2
- OR4D11 | c.405C>T p.I135= | Silent (SNP) | VAF 148/367 reads (40%) | catalogued as COSV57584463; called by muse, mutect2, varscan2
- OR5T2 | c.681T>G p.S227= | Silent (SNP) | VAF 129/312 reads (41%) | catalogued as COSV57588476, COSV57589308, COSV57590451; called by muse, mutect2, varscan2
- PCDHB2 | c.1884C>T p.T628= | Silent (SNP) | VAF 66/211 reads (31%) | catalogued as COSV50567523; called by muse, mutect2, varscan2
- PCDHGA8 | c.1509G>A p.S503= | Silent (SNP) | VAF 41/120 reads (34%) | catalogued as rs1438978424, COSV53922298; called by muse, mutect2, varscan2
- POLQ | c.594C>T p.I198= | Silent (SNP) | VAF 69/179 reads (39%) | catalogued as COSV51748945; called by muse, mutect2, varscan2
- PRAMEF20 | c.447G>A p.V149= | Silent (SNP) | VAF 267/712 reads (38%) | called by muse, mutect2, varscan2
- PRICKLE1 | c.1123T>C p.L375= | Silent (SNP) | VAF 45/136 reads (33%) | catalogued as COSV61542630, COSV61544588; called by muse, mutect2, varscan2
- RIMBP3 | c.4677C>A p.L1559= | Silent (SNP) | VAF 19/84 reads (23%) | called by muse, mutect2, varscan2
- RIMS2 | c.1269T>G p.S423= (on ENST00000666250 / NM_001348490.2; = p.S231= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 11/148 reads (7%) | catalogued as COSV51651026, COSV51655287, COSV51702036; called by muse, mutect2
- RORB | c.1038T>C p.S346= (on ENST00000396204 / NM_001365023.1; = p.S335= on NM_006914.4) | Silent (SNP) | VAF 105/243 reads (43%) | catalogued as rs764322019, COSV65334693; called by muse, mutect2, varscan2
- ROS1 | c.453G>A p.P151= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as rs777706763, COSV63853442; called by muse, mutect2, varscan2
- SLFN5 | c.2511C>T p.T837= | Silent (SNP) | VAF 53/140 reads (38%) | catalogued as rs148974561; called by muse, mutect2, varscan2
- SLITRK1 | c.2079G>A p.S693= | Silent (SNP) | VAF 37/67 reads (55%) | catalogued as COSV65674931; called by muse, mutect2, varscan2
- SLITRK1 | c.672A>G p.K224= | Silent (SNP) | VAF 41/143 reads (29%) | catalogued as rs1208965366, COSV65674934; called by muse, mutect2, varscan2
- SLITRK2 | c.1503G>C p.L501= | Silent (SNP) | VAF 322/362 reads (89%) | catalogued as COSV59424195, COSV59428066; called by muse, mutect2, varscan2
- SNRPN | c.375T>G p.A125= | Silent (SNP) | VAF 56/143 reads (39%) | catalogued as COSV57595169; called by muse, mutect2, varscan2
- SOX5 | c.522A>G p.K174= | Silent (SNP) | VAF 64/179 reads (36%) | catalogued as COSV58624954; called by muse, mutect2, varscan2
- SPTA1 | c.5448A>G p.E1816= | Silent (SNP) | VAF 56/170 reads (33%) | catalogued as COSV100935700, COSV63751113; called by muse, mutect2, varscan2
- SUSD2 | c.1110G>A p.A370= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs765294488, COSV64202786; called by muse, mutect2, varscan2
- TAAR9 | c.147A>G p.G49= | Silent (SNP) | VAF 39/98 reads (40%) | catalogued as COSV71512209; called by muse, mutect2, varscan2
- TM6SF1 | c.456T>G p.V152= | Silent (SNP) | VAF 104/240 reads (43%) | catalogued as COSV51943703; called by muse, mutect2, varscan2
- UNC13C | c.6375A>G p.E2125= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV52857892; called by muse, mutect2, varscan2
- USH2A | c.5112C>T p.N1704= | Silent (SNP) | VAF 82/199 reads (41%) | catalogued as COSV56350008; called by muse, mutect2, varscan2
- VCAN | c.2895T>G p.T965= | Silent (SNP) | VAF 106/252 reads (42%) | catalogued as rs141161041; called by muse, varscan2
- VCAN | c.2976A>C p.S992= | Silent (SNP) | VAF 55/135 reads (41%) | catalogued as COSV54101787; called by muse, varscan2
- VPS13D | c.9972C>T p.C3324= | Silent (SNP) | VAF 38/93 reads (41%) | catalogued as COSV50629924; called by muse, mutect2, varscan2
- XIRP2 | c.696G>A p.V232= (on ENST00000628543; = p.V407= on NM_152381.6) | Silent (SNP) | VAF 88/251 reads (35%) | catalogued as COSV54691274; called by muse, mutect2, varscan2
- ZNF208 | c.627T>G p.A209= | Silent (SNP) | VAF 53/158 reads (34%) | catalogued as COSV68101362; called by muse, mutect2, varscan2
- ZNF300 | c.123C>T p.Y41= | Silent (SNP) | VAF 87/228 reads (38%) | catalogued as COSV51033074; called by muse, varscan2
- DCHS2 | n.2320T>A | RNA (SNP) | VAF 11/40 reads (28%) | catalogued as COSV59722257; called by muse, mutect2, varscan2
- FAM169B | n.407G>T | RNA (SNP) | VAF 69/193 reads (36%) | catalogued as rs767177556, COSV60568351; called by muse, mutect2, varscan2
- GRIA2 | c.2406+523A>C | Intron (SNP) | VAF 39/88 reads (44%) | catalogued as COSV52384523; called by muse, mutect2, varscan2
- NACA | c.70+4412T>G | Intron (SNP) | VAF 48/108 reads (44%) | catalogued as COSV100771404; called by muse, mutect2, varscan2
- PDE4B | c.281+74082_281+74083del | Intron (DEL) | VAF 23/69 reads (33%) | called by mutect2, pindel, varscan2
- SNORD116-4 | n.28dup | RNA (INS) | VAF 84/216 reads (39%) | catalogued as rs753149037; called by mutect2, varscan2
- ST8SIA2 | chr15:92472376 A>G | 3'Flank (SNP) | VAF 54/147 reads (37%) | called by muse, mutect2, varscan2
- ZNF611 | c.*1A>G | 3'UTR (SNP) | VAF 77/204 reads (38%) | catalogued as COSV100160359; called by muse, mutect2, varscan2
